Somatic mutation profile of tumor specimen 0DVJOM from CCDI case PBCMYB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 9.5 years (3,479 days).
Specimen 0DVJOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78d8c879-35f5-4364-ac50-25417226f2ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3967d893-bda7-48cd-9179-f1b055115503

The open-access MAF lists 64 somatic variants for this specimen: 41 protein-altering or splice-affecting, 11 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 5, Intron 5, 3'UTR 3, Splice Site 2, 5'UTR 2, Frame Shift Del 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KANSL1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 121/374 reads (32%) | catalogued as rs149830411; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 346/639 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 128/299 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.638); catalogued as rs727504317, CM076269, COSV61068427, COSV61072298; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACCS | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 102/583 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.752); catalogued as rs1455669046, COSV55459353; called by muse, mutect2, varscan2
- ACOT12 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 204/713 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142273702; called by muse, mutect2, varscan2
- ARHGAP32 | c.3304C>T p.R1102* (on ENST00000310343 / NM_001378025.1; = p.R753* on NM_014715.4) | Nonsense Mutation (SNP) | VAF 195/590 reads (33%) | catalogued as COSV104403863; called by muse, mutect2, varscan2
- ATF1 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 172/345 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV100016161; called by muse, mutect2, varscan2
- BUB3 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 108/338 reads (32%) | catalogued as COSV60593567; called by muse, mutect2, varscan2
- CXXC4 | c.799G>A p.V267I | Missense Mutation (SNP) | VAF 97/488 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.346); catalogued as rs192774242; called by muse, mutect2, varscan2
- DGCR2 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 148/483 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763137065, COSV54219910; called by muse, mutect2, varscan2
- DOC2A | c.1183G>T p.G395W | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV58752441; called by muse, mutect2, varscan2
- GBP5 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 236/859 reads (27%) | catalogued as COSV58594400; called by muse, mutect2, varscan2
- LAMP3 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 148/495 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as rs777689064, COSV99660803; called by muse, mutect2, varscan2
- LRIT2 | c.662C>A p.P221Q | Missense Mutation (SNP) | VAF 147/397 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100259501; called by muse, mutect2, varscan2
- MUC5B | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 229/689 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.336); catalogued as rs369710646; called by muse, mutect2, varscan2
- NPC1 | c.1870G>A p.V624I | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs76615690; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5J2 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 379/1177 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56620074; called by muse, mutect2, varscan2
- POLQ | c.6505C>T p.R2169C | Missense Mutation (SNP) | VAF 132/555 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs776545160; called by muse, mutect2, varscan2
- SLC9A3 | c.1654C>T p.R552C | Missense Mutation (SNP) | VAF 116/486 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs536043517; called by muse, mutect2, varscan2
- SSC5D | c.1672G>A p.A558T | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs1206866487; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4699G>A p.D1567N | Missense Mutation (SNP) | VAF 111/660 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769228527, COSV100835855; called by muse, mutect2, varscan2
- ATP6V1H | c.433A>T p.I145F | Missense Mutation (SNP) | VAF 505/936 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BAHCC1 | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- BEND5 | c.745+2T>G p.X249_splice | Splice Site (SNP) | VAF 143/575 reads (25%) | called by mutect2, varscan2
- COPA | c.31C>T p.R11W | Missense Mutation (SNP) | VAF 168/358 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FUOM | c.67G>C p.G23R | Missense Mutation (SNP) | VAF 81/224 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HCRTR2 | c.980A>T p.K327M | Missense Mutation (SNP) | VAF 49/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IL22RA2 | c.294-1G>A p.X98_splice | Splice Site (SNP) | VAF 76/223 reads (34%) | called by muse, mutect2, varscan2
- KRTAP15-1 | c.86T>C p.F29S | Missense Mutation (SNP) | VAF 136/488 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MAGEA10 | c.659G>A p.S220N | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- MBIP | c.837G>T p.E279D | Missense Mutation (SNP) | VAF 160/574 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PCDHB9 | c.650G>T p.G217V | Missense Mutation (SNP) | VAF 152/568 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PRUNE2 | c.4757T>C p.L1586P | Missense Mutation (SNP) | VAF 216/539 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RARB | c.268G>T p.V90F (on ENST00000383772 / NM_001290216.2; = p.V83F on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 153/501 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS8 | c.494C>G p.S165C (on ENST00000367556 / NM_001369564.2; = p.S183C on NM_033345.3) | Missense Mutation (SNP) | VAF 266/535 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK6 | c.784A>T p.K262* | Nonsense Mutation (SNP) | VAF 191/480 reads (40%) | called by muse, mutect2, varscan2
- SORCS1 | c.2548T>C p.S850P | Missense Mutation (SNP) | VAF 120/514 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.034); called by muse, varscan2
- SPAG16 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 232/853 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNPO2L | c.1210del p.E404Nfs*41 (on ENST00000394810 / NM_001114133.3; = p.E180Nfs*41 on NM_024875.5) | Frame Shift Del (DEL) | VAF 106/276 reads (38%) | called by mutect2, varscan2
- UQCRFS1 | c.771C>A p.N257K | Missense Mutation (SNP) | VAF 170/754 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VPS13D | c.9946C>G p.R3316G | Missense Mutation (SNP) | VAF 88/608 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- BUB1 | c.2112C>T p.D704= | Silent (SNP) | VAF 145/508 reads (29%) | catalogued as rs1801395; called by muse, mutect2, varscan2
- CDK5R1 | c.69C>G p.T23= | Silent (SNP) | VAF 100/274 reads (36%) | called by mutect2, varscan2
- COBL | c.1602C>T p.G534= | Silent (SNP) | VAF 156/534 reads (29%) | catalogued as rs767196099, COSV54343642; called by muse, mutect2, varscan2
- CRELD2 | c.843C>T p.Y281= | Silent (SNP) | VAF 82/306 reads (27%) | catalogued as rs556187594; called by muse, mutect2, varscan2
- PRKCH | c.333G>C p.T111= | Silent (SNP) | VAF 127/459 reads (28%) | called by muse, mutect2, varscan2
- PTGDR | c.69C>T p.G23= | Silent (SNP) | VAF 164/631 reads (26%) | catalogued as COSV60094946; called by muse, mutect2, varscan2
- RNF225 | c.183G>T p.P61= | Silent (SNP) | VAF 48/142 reads (34%) | catalogued as rs1478656472; called by muse, varscan2
- TEP1 | c.6498G>A p.R2166= | Silent (SNP) | VAF 128/482 reads (27%) | called by muse, mutect2, varscan2
- USH2A | c.7056T>G p.P2352= | Silent (SNP) | VAF 174/670 reads (26%) | called by muse, mutect2, varscan2
- ZNF320 | c.231A>G p.Q77= | Silent (SNP) | VAF 124/448 reads (28%) | called by muse, mutect2, varscan2
- ZNF735 | c.189C>T p.D63= | Silent (SNP) | VAF 107/539 reads (20%) | called by muse, mutect2, varscan2
- BBOF1 | c.*81A>T | 3'UTR (SNP) | VAF 25/652 reads (4%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 6/123 reads (5%) | called by muse, mutect2
- CDK5R1 | c.-72G>T | 5'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 7/130 reads (5%) | called by muse, mutect2
- ERCC6L2 | c.471+29C>G | Intron (SNP) | VAF 14/382 reads (4%) | called by muse, mutect2
- ERGIC3 | c.685+47C>T | Intron (SNP) | VAF 106/260 reads (41%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.*12C>T | 3'UTR (SNP) | VAF 34/498 reads (7%) | catalogued as rs992162918; called by muse, mutect2
- LYN | c.*15del | 3'UTR (DEL) | VAF 68/399 reads (17%) | called by mutect2, varscan2
- MUC19 | n.19532T>C | RNA (SNP) | VAF 256/477 reads (54%) | catalogued as rs796068417; called by muse, mutect2, varscan2
- RADIL | c.2290+51G>A | Intron (SNP) | VAF 40/153 reads (26%) | catalogued as rs748227306, COSV68203089; called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 18/164 reads (11%) | called by muse, varscan2
- ZNF570 | chr19:37467927 G>T | 5'Flank (SNP) | VAF 101/388 reads (26%) | catalogued as rs1184662191; called by muse, mutect2, varscan2
